Somatic mutation profile of tumor specimen ALCH-AF49-TTP1-A (aliquot ALCH-AF49-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AF49, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.6 years (18,837 days).
Specimen ALCH-AF49-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4474c97a-d3b5-42ec-b6c1-bb8390d62437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF49-NB1-A (Blood Derived Normal), aliquot ALCH-AF49-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a585555b-6f62-4a07-b573-5389a4d85c2d

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 3, 3'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 55/748 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GRIN2B | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886041095, COSV74205159; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 56/644 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- BCAS3 | c.2287T>A p.S763T (on ENST00000390652 / NM_001353144.2; = p.S748T on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/436 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV101177071; called by muse, mutect2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs762874947; called by mutect2, varscan2
- GRM5 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 28/569 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs756243558; called by muse, mutect2
- HEATR6 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 30/495 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs541726986, COSV51746220; called by muse, mutect2
- SGIP1 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 50/591 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs752060294; called by muse, mutect2
- WDR62 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs751622020, COSV54334763; called by muse, mutect2
- ATP12A | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2
- INTS12 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 41/812 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.388); called by muse, mutect2
- MIDEAS | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHCBP1 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2
- MAGEC2 | c.330C>T p.S110= | Silent (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- PLA2G4C | c.786G>A p.L262= | Silent (SNP) | VAF 19/356 reads (5%) | called by muse, mutect2
- SLC29A4 | c.864C>T p.V288= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs745499072, COSV51874030; called by muse, varscan2
- TTC14 | c.1560A>G p.S520= | Silent (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- ZMAT4 | c.81G>A p.S27= | Silent (SNP) | VAF 24/356 reads (7%) | catalogued as rs186839983; called by muse, mutect2
- AC022415.2 | c.*2896C>T | 3'UTR (SNP) | VAF 17/281 reads (6%) | catalogued as rs1182983941, COSV59463906; called by muse, mutect2
- PEA15 | c.-2-2915C>T | Intron (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- SCN4B | c.*2330T>A | 3'UTR (SNP) | VAF 32/432 reads (7%) | catalogued as rs1445145488, COSV100228811; called by muse, mutect2
- SYNE1 | c.2250+14G>A | Intron (SNP) | VAF 32/518 reads (6%) | called by muse, mutect2
- TRPA1 | c.1364+27A>G | Intron (SNP) | VAF 26/850 reads (3%) | called by muse, mutect2
- TSPAN5 | c.*5C>T | 3'UTR (SNP) | VAF 11/187 reads (6%) | catalogued as COSV59875288; called by muse, mutect2
